TCGA case TCGA-73-4659 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cd0dc947-b708-464e-beb7-954c9d4583e7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Dead; Days to death: 711 days (1.9 years).

Diagnoses (4)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 66.4 years (24,253 days); Year of diagnosis: 2006; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed Disodium; Initial disease status: Progressive Disease; Days to treatment start: 257 days; Days to treatment end: 298 days; Number of cycles: 3; Treatment dose: 3,000 mg; Prescribed dose: 500; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib; Initial disease status: Progressive Disease; Days to treatment start: 312 days; Days to treatment end: 406 days (1.1 years); Number of cycles: 5; Treatment dose: 9,000 mg; Prescribed dose: 150; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Progressive Disease; Days to treatment start: 337 days; Days to treatment end: 337 days; Treatment dose: 2,200 cGy; Course number: 1; Number of fractions: 1; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine; Initial disease status: Progressive Disease; Days to treatment start: 410 days (1.1 years); Days to treatment end: 452 days (1.2 years); Number of cycles: 2; Treatment dose: 300 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Progressive Disease; Days to treatment start: 473 days (1.3 years); Days to treatment end: 494 days (1.4 years); Number of cycles: 4; Treatment dose: 150 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 516 days (1.4 years); Days to treatment end: 529 days (1.4 years); Treatment dose: 3,000 cGy; Course number: 2; Number of fractions: 10; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 539 days (1.5 years); Days to treatment end: 581 days (1.6 years); Number of cycles: 2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 546 days (1.5 years); Days to treatment end: 581 days (1.6 years); Number of cycles: 2; Treatment dose: 300 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 602 days (1.6 years); Days to treatment end: 609 days (1.7 years); Number of cycles: 2; Treatment dose: 200 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Aurora Kinase/VEGFR2 Inhibitor CYC116; Days to treatment start: 624 days (1.7 years); Days to treatment end: 657 days (1.8 years); Number of cycles: 3; Treatment dose: 15,120 mg; Prescribed dose: 720; Prescribed dose units: mg; Route of administration: Oral.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 66.5 years (24,288 days); Days to diagnosis: 35 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site.
3. Recurrence of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 66.5 years (24,300 days); Days to diagnosis: 47 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site.
4. Metastasis of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 67.3 years (24,569 days); Days to diagnosis: 316 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.

Follow-up (6 entries)
- Day 35 (post initial treatment): Progression or recurrence: Yes.
- Day 47 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 47 days; Evidence of recurrence type: Convincing Image Source.
- Day 316 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 316 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 711 days (1.9 years); Disease response: With Tumor.
- Karnofsky performance status: 0; Timepoint: Other.
- Karnofsky performance status: 90; ECOG performance status: 0; Timepoint: Other.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 12; Tobacco smoking onset year: 1974; Tobacco smoking quit year: 1986.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-73-4659-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 1; Shortest dimension: 0.4.
  Slide TCGA-73-4659-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 90; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-73-4659-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 80; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-73-4659-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-73-4659-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2.5; Intermediate dimension: 2.2; Shortest dimension: 0.6.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 3; Anatomic organ subdivision: R-Upper; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No.
- Drug treatment 1: Regimen number: 7; Pharmaceutical therapy drug name: Taxol; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 8; Pharmaceutical therapy drug name: CYC-116/Cyclocel; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Protocol.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 3: Regimen number: 3; Pharmaceutical therapy drug name: Alimta; Therapy regimen: Progression.
- Drug treatment 5: Regimen number: 4; Pharmaceutical therapy drug name: Erlotonib; Therapy regimen: Progression.
- Drug treatment 6: Regimen number: 4; Pharmaceutical therapy drug name: Docetoxel/Taxotere; Therapy regimen: Progression.
- Drug treatment 7: Regimen number: 6; Therapy regimen: Progression.
- Drug treatment 8: Regimen number: 5; Therapy regimen: Progression.
- Radiation treatment 1: Radiation type other: Gamma Knife; Therapy regimen: Progression.
- Follow-up form 1: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 2: Lost to follow-up: No; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 2, New neoplasm event types: New tumor event type: Locoregional Recurrence.
- Follow-up form 2, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Follow-up form 3: Lost to follow-up: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No.
- Follow-up form 3, New neoplasm event types: New tumor event type: Distant Metastasis.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 711 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 711 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 35 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-73-4659-01A-01D-1204-01): tumor purity 0.33, ploidy 3.5, whole-genome doublings 1.
